Somatic mutation profile of tumor specimen TCGA-33-4547-01A (aliquot TCGA-33-4547-01A-01D-1267-08) from TCGA case TCGA-33-4547, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.6 years (25,056 days).
Specimen TCGA-33-4547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3090e09-c200-4cf2-aca5-d2fc7b5022a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4547-11A (Solid Tissue Normal), aliquot TCGA-33-4547-11A-01D-1267-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc7c4d98-d91a-49c9-997d-c79d56335c0d

The open-access MAF lists 207 somatic variants for this specimen: 151 protein-altering or splice-affecting, 50 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 50, Nonsense Mutation 14, Splice Site 3, Splice Region 2, Frame Shift Del 2, Intron 2, 3'UTR 1, 5'UTR 1, 5'Flank 1, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | hotspot (GDC flag); catalogued as COSV61685158, COSV61687482, COSV61687686; called by muse, mutect2, varscan2
- TP53 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1060501191, COSV52666332, COSV52700326, COSV52746468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC1 | c.584C>T p.S195L | Missense Mutation (SNP) | VAF 178/722 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV60681310; called by muse, mutect2, varscan2
- AC004922.1 | c.636C>G p.F212L | Missense Mutation (SNP) | VAF 46/233 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV53555765, COSV53555833; called by muse, mutect2, varscan2
- ADCY2 | c.1858C>T p.L620F | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.473); catalogued as COSV57860798, COSV57900751; called by muse, mutect2, varscan2
- ADGRG6 | c.2213C>G p.S738C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.706); catalogued as COSV99748792; called by muse, mutect2, varscan2
- ADGRV1 | c.6916G>C p.E2306Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV67979448; called by muse, mutect2, varscan2
- AHNAK2 | c.2126T>A p.V709E | Missense Mutation (SNP) | VAF 146/307 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV60908998; called by muse, mutect2, varscan2
- ALMS1 | c.7603G>A p.D2535N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52503974, COSV52522657; called by muse, mutect2, varscan2
- AMPH | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); catalogued as rs368302578; called by muse, mutect2, varscan2
- AOX1 | c.1422G>C p.K474N | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV65980312; called by muse, mutect2, varscan2
- ARHGEF3 | c.383T>C p.F128S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV56323982; called by muse, mutect2, varscan2
- ATP13A4 | c.2827C>T p.L943F | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.14); catalogued as rs1329495064, COSV61316900; called by muse, mutect2, varscan2
- BBS7 | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.382); catalogued as COSV52654874; called by muse, mutect2
- BRAP | c.1350G>C p.E450D | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV59535680; called by muse, mutect2, varscan2
- BUB1 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV57061535; called by muse, mutect2, varscan2
- C19orf54 | c.910C>T p.Q304* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV54573492; called by muse, mutect2, varscan2
- CACNA1I | c.3984C>G p.F1328L | Missense Mutation (SNP) | VAF 47/220 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60802170, COSV60809075; called by muse, mutect2, varscan2
- CCDC158 | c.2260G>T p.E754* | Nonsense Mutation (SNP) | VAF 41/162 reads (25%) | catalogued as COSV66355301; called by muse, mutect2, varscan2
- CCN6 | c.625T>A p.C209S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs782088046, COSV57888848; called by muse, mutect2, varscan2
- CD164 | c.251A>G p.E84G | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV51532943; called by muse, mutect2, varscan2
- CD68 | c.773C>G p.S258W | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV51509991, COSV51511308; called by muse, mutect2, varscan2
- CEP19 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV56359123, COSV99582493; called by muse, mutect2, varscan2
- CHUK | c.410A>G p.E137G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.871); catalogued as COSV64917323; called by muse, mutect2, varscan2
- CLTCL1 | c.3121A>T p.M1041L | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.743); catalogued as COSV54225971; called by muse, mutect2, varscan2
- COL5A1 | c.2646+1G>C p.X882_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV65665729; called by muse, mutect2, varscan2
- CSMD3 | c.2159C>T p.P720L (on ENST00000297405 / NM_001363185.1; = p.P616L on NM_052900.3) | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV52113698; called by muse, varscan2
- DDX59 | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58750635; called by muse, mutect2, varscan2
- DDX59 | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as COSV58750682; called by muse, varscan2
- DNAH9 | c.8564A>C p.Y2855S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV52336880; called by muse, mutect2
- DNAJC11 | c.1135C>T p.H379Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.189); catalogued as COSV53784523; called by muse, mutect2, varscan2
- DNM3 | c.1048C>T p.Q350* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV62453806; called by muse, mutect2, varscan2
- DPEP1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs774400088, COSV55359107; called by muse, mutect2, varscan2
- DPYSL5 | c.408G>T p.W136C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); catalogued as COSV56509341; called by muse, mutect2, varscan2
- EIF4A2 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 33/470 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV60623812, COSV60624846; called by muse, mutect2
- EPC1 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.573); catalogued as COSV53923486; called by muse, mutect2, varscan2
- FKBP3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.22); catalogued as COSV53531338; called by muse, mutect2, varscan2
- FMN2 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.378); catalogued as COSV60419258, COSV60445924; called by muse, mutect2, varscan2
- FRMD6 | c.918C>A p.C306* (on ENST00000344768 / NM_001267046.2; = p.C298* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV61086727; called by muse, mutect2, varscan2
- FSHR | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.372); catalogued as COSV100436296, COSV58618781; called by muse, mutect2, varscan2
- FUT9 | c.682G>A p.D228N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.102); catalogued as COSV56142597; called by muse, mutect2, varscan2
- GALNT12 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs376894835, COSV66662217; called by muse, mutect2, varscan2
- GALNT17 | c.1527C>A p.F509L | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV61149743, COSV61182406; called by muse, mutect2, varscan2
- GNPTAB | c.2054C>G p.S685* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV54777289, COSV54780515; called by mutect2, varscan2
- GOLGA3 | c.2176C>G p.L726V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.144); catalogued as COSV52626384; called by muse, mutect2, varscan2
- GPR6 | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 44/339 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.22); catalogued as COSV51571149; called by muse, varscan2
- HAPLN3 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772342574, COSV62084471; called by muse, mutect2, varscan2
- HCFC2 | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV57558050; called by muse, mutect2, varscan2
- HOOK3 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs777110373, COSV56879587; called by muse, mutect2, varscan2
- HSPA4L | c.850C>T p.L284F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56543961; called by muse, mutect2, varscan2
- HSPG2 | c.2948G>C p.R983T | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV65969435; called by muse, mutect2, varscan2
- IGKV3-15 | c.59G>C p.G20A | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); catalogued as rs745796620; called by muse, mutect2
- IL1RL1 | c.800A>T p.Q267L | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV52112681; called by muse, mutect2
- ITGA8 | c.2136C>A p.S712R | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV65225367; called by muse, mutect2, varscan2
- ITSN1 | c.624-2A>T p.X208_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV66081271; called by muse, mutect2
- JAKMIP1 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51523275; called by muse, mutect2, varscan2
- KCTD9 | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55339357; called by muse, mutect2, varscan2
- KIF1B | c.1397C>G p.S466C (on ENST00000377086 / NM_001365952.1; = p.S420C on NM_015074.3) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.723); catalogued as COSV55804240; called by muse, mutect2, varscan2
- KIF1B | c.2162G>A p.R721Q (on ENST00000377086 / NM_001365952.1; = p.R675Q on NM_015074.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs763303622, COSV55802713; called by muse, mutect2, varscan2
- LEPR | c.195G>C p.E65D | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV60748442; called by muse, mutect2, varscan2
- LIPC | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.776); catalogued as rs145742763; called by muse, varscan2
- LYST | c.4958C>A p.S1653* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV67703831; called by muse, mutect2, varscan2
- MAPKAP1 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.449); catalogued as COSV56365244; called by muse, mutect2, varscan2
- MCFD2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV60177763; called by muse, mutect2, varscan2
- MCL1 | c.559C>T p.R187W | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as COSV57189959; called by muse, mutect2, varscan2
- MCM4 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs1003322607, COSV50621505; called by muse, mutect2, varscan2
- MCMBP | c.331C>G p.Q111E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.216); catalogued as COSV100750081, COSV63508594; called by mutect2, varscan2
- MECOM | c.568T>G p.C190G (on ENST00000468789 / NM_001105078.4; = p.C378G on NM_004991.4) | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52960494; called by muse, mutect2, varscan2
- MEGF8 | c.6314G>T p.G2105V (on ENST00000251268 / NM_001271938.2; = p.G2038V on NM_001410.3) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV52076719; called by muse, mutect2, varscan2
- MMP16 | c.422C>G p.P141R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV54153026, COSV54177763; called by muse, mutect2, varscan2
- MYH11 | c.2253C>G p.I751M | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV55544690; called by muse, mutect2, varscan2
- MYL6 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52878336; called by muse, mutect2, varscan2
- NDRG3 | c.338T>C p.M113T (on ENST00000349004 / NM_032013.4; = p.M101T on NM_022477.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV62421139; called by muse, mutect2, varscan2
- NDUFAF5 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65246561; called by muse, mutect2, varscan2
- NSDHL | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs782208947, COSV64743285; called by muse, mutect2, varscan2
- OR10W1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV67720243; called by muse, mutect2, varscan2
- OR1S2 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138124206, COSV56919939; called by muse, mutect2, varscan2
- OTULIN | c.1003G>C p.E335Q | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52505012; called by muse, mutect2
- PCDH10 | c.2393A>C p.N798T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV52088396; called by muse, mutect2, varscan2
- PCDHA6 | c.2013G>C p.E671D | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.011); catalogued as COSV65342282; called by muse, mutect2, varscan2
- PDCD11 | c.2902G>C p.E968Q | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.625); catalogued as COSV63933168; called by muse, mutect2, varscan2
- PHACTR2 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV59850940; called by muse, mutect2, varscan2
- PHLDB1 | c.2678G>A p.R893K | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.366); catalogued as COSV61876740, COSV61879139; called by muse, mutect2, varscan2
- PIKFYVE | c.3332C>G p.S1111C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV52237669; called by muse, mutect2, varscan2
- PIKFYVE | c.3677C>G p.S1226C | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52237682, COSV52246676; called by muse, mutect2, varscan2
- PKLR | c.1270-1G>A p.X424_splice | Splice Site (SNP) | VAF 33/141 reads (23%) | catalogued as CS052052, COSV61360566; called by muse, mutect2, varscan2
- PKLR | c.1059G>C p.Q353H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61360569; called by muse, mutect2, varscan2
- PLPPR5 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.264); catalogued as COSV54169715; called by muse, mutect2, varscan2
- PLTP | c.330C>T p.F110= | Splice Region (SNP) | VAF 35/174 reads (20%) | catalogued as COSV62463914; called by muse, mutect2, varscan2
- PPFIA2 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100332628, COSV61022238; called by muse, mutect2, varscan2
- PPFIA3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV61949793, COSV61951470; called by muse, mutect2, varscan2
- PRDM12 | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV53389811; called by muse, mutect2, varscan2
- PRPF40B | c.2464G>C p.E822Q (on ENST00000380281; = p.E809Q on NM_012272.3) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.515); catalogued as COSV53298471; called by muse, mutect2, varscan2
- PTPN9 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV60722717; called by muse, mutect2, varscan2
- RASA2 | c.1816C>G p.L606V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53936866, COSV53947414, COSV99655971; called by muse, mutect2
- RHPN1 | c.354G>C p.K118N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV56645060; called by muse, mutect2, varscan2
- RIT1 | c.324C>A p.F108L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.124); catalogued as COSV64170867; called by muse, mutect2, varscan2
- RNASEK | c.125C>A p.S42* (on ENST00000548577; = p.S3* on NM_001004333.5) | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52348788; called by muse, mutect2, varscan2
- RNF10 | c.795C>G p.I265M | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58043233, COSV58043787; called by muse, mutect2, varscan2
- RTP2 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.278); catalogued as rs781573795, COSV64078828; called by muse, mutect2, varscan2
- RYR2 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.2); catalogued as rs1470689668, COSV63665957; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SARS1 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV52319800; called by muse, mutect2
- SCCPDH | c.869T>A p.M290K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.664); catalogued as COSV63618129; called by muse, mutect2, varscan2
- SGO2 | c.2193T>G p.N731K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV63414096; called by muse, mutect2, varscan2
- SHROOM3 | c.2677C>T p.Q893* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV56024111, COSV56024592; called by muse, mutect2
- SIGLEC8 | c.1131C>G p.F377L | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV58472127; called by muse, mutect2, varscan2
- SLC16A4 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV63916028; called by muse, mutect2, varscan2
- SLC18A3 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV60319635; called by muse, mutect2, varscan2
- SLC25A41 | c.81C>G p.I27M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.041); catalogued as COSV51190520; called by muse, mutect2, varscan2
- SLC30A3 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.183); catalogued as rs956968053, COSV51984161, COSV99273551; called by muse, mutect2, varscan2
- SLC35E2A | n.1146C>T | Splice Region (SNP) | VAF 10/63 reads (16%) | catalogued as rs1340931381, COSV55802937; called by muse, mutect2, varscan2
- SMC1B | c.1435C>G p.L479V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV62528485; called by muse, mutect2, varscan2
- SND1 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.176); catalogued as rs1182223852, COSV61235941; called by muse, mutect2
- SNRNP70 | c.309G>C p.K103N | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.893); catalogued as COSV55505068; called by muse, mutect2, varscan2
- SPAG4 | c.194G>C p.G65A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.53); catalogued as COSV65330058; called by muse, varscan2
- SPANXN5 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV64968656; called by mutect2, varscan2
- SPATA7 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV50416115; called by mutect2, varscan2
- SRSF9 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV57584205; called by muse, mutect2, varscan2
- ST8SIA4 | c.434T>A p.V145D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | PolyPhen probably damaging (1); catalogued as COSV51506704; called by muse, mutect2, varscan2
- STXBP5L | c.3375G>A p.M1125I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV56502083; called by muse, varscan2
- SYNE1 | c.9577G>A p.E3193K (on ENST00000367255 / NM_182961.4; = p.E3200K on NM_033071.3) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs761121679, COSV54919213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNGR1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs558152755, COSV59559483; called by muse, mutect2, varscan2
- TARBP1 | c.2344C>G p.L782V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV50178793; called by muse, mutect2, varscan2
- TARBP1 | c.2248C>A p.R750S | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50178833, COSV50214063; called by muse, mutect2, varscan2
- TBX18 | c.1543C>G p.Q515E | Missense Mutation (SNP) | VAF 42/246 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV63736201, COSV63738217, COSV63738371; called by muse, mutect2, varscan2
- TET2 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.469); catalogued as COSV54399149; called by muse, mutect2, varscan2
- TEX47 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV51878307; called by muse, mutect2, varscan2
- THSD7B | c.1471T>G p.S491A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV55659373; called by muse, varscan2
- TRIOBP | c.1420C>G p.R474G | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100731133; called by muse, varscan2
- TSEN15 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs771754885, COSV62294076; called by muse, mutect2
- TSHZ2 | c.2768A>G p.H923R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs781729711, COSV61587145; called by muse, mutect2, varscan2
- TTN | c.26894G>T p.S8965I (on ENST00000591111; = p.S8038I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | PolyPhen benign (0.122); catalogued as COSV59910417; called by muse, mutect2, varscan2
- TUBG2 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.083); catalogued as COSV52216891; called by muse, mutect2
- UBR4 | c.3892C>G p.L1298V | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.931); catalogued as COSV64383555; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2148A>G p.I716M | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV54434957; called by muse, mutect2, varscan2
- VAPB | c.299C>G p.S100* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as COSV55666477; called by muse, mutect2, varscan2
- VPS13C | c.5963C>G p.S1988* (on ENST00000644861 / NM_020821.3; = p.S1945* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 38/74 reads (51%) | catalogued as COSV51125219; called by muse, mutect2, varscan2
- ZBTB1 | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62437421; called by muse, mutect2, varscan2
- ZBTB1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV62437429; called by muse, mutect2, varscan2
- ZFP90 | c.1524G>C p.R508S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.813); catalogued as COSV68050674; called by muse, mutect2, varscan2
- ZNF10 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.745); catalogued as COSV50211659; called by muse, mutect2, varscan2
- ZNF256 | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56596435; called by muse, mutect2, varscan2
- ZNF319 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746147338, COSV54621263; called by muse, mutect2, varscan2
- ZNF565 | c.1385A>T p.K462M (on ENST00000355114; = p.K422M on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.294); catalogued as COSV58410403; called by muse, mutect2, varscan2
- ZNF804A | c.708C>A p.Y236* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV56437421; called by muse, mutect2, varscan2
- ZSWIM4 | c.1672C>G p.P558A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV54319693; called by muse, mutect2
- LYST | c.6793_6799del p.L2265Ifs*29 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | called by mutect2, pindel, varscan2
- MRC1 | c.2720G>A p.G907E | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NACC2 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRAF3 | c.1644_1650del p.Y548* | Frame Shift Del (DEL) | VAF 69/135 reads (51%) | called by mutect2, pindel, varscan2
- ACTA1 | c.885G>T p.L295= | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV64203476; called by muse, mutect2
- AKAP9 | c.1875G>C p.L625= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV62339912; called by muse, mutect2
- ARHGEF17 | c.3585G>A p.E1195= | Silent (SNP) | VAF 58/337 reads (17%) | catalogued as COSV55230051; called by muse, mutect2, varscan2
- C1orf141 | c.1197C>T p.A399= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV63992228; called by muse, mutect2, varscan2
- CCDC150 | c.330C>G p.L110= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV55872214; called by muse, mutect2, varscan2
- CLCN7 | c.1692G>A p.L564= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as COSV51969020; called by muse, mutect2, varscan2
- CRNN | c.1215G>A p.Q405= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV55120903; called by muse, mutect2, varscan2
- CRTC1 | c.609A>G p.A203= | Silent (SNP) | VAF 61/287 reads (21%) | catalogued as COSV58716806; called by muse, mutect2, varscan2
- DARS2 | c.1878G>C p.L626= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV53405952; called by muse, mutect2, varscan2
- DDX59 | c.444C>T p.L148= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV58750659; called by muse, varscan2
- DIP2C | c.1452C>T p.F484= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as COSV55148013; called by muse, mutect2, varscan2
- ECM2 | c.1524C>G p.T508= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV60738853, COSV60739206; called by muse, mutect2, varscan2
- EP400 | c.483C>G p.L161= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV57764561, COSV57770019; called by muse, mutect2, varscan2
- FBXO46 | c.813C>A p.P271= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV58347907; called by muse, mutect2, varscan2
- FCGRT | c.513C>T p.A171= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV55528894; called by muse, mutect2, varscan2
- FOXD4L1 | c.384C>G p.L128= | Silent (SNP) | VAF 34/550 reads (6%) | catalogued as COSV52073105; called by muse, mutect2
- FOXR1 | c.729C>T p.S243= | Silent (SNP) | VAF 34/168 reads (20%) | catalogued as COSV57651428; called by muse, mutect2, varscan2
- GBP7 | c.948A>T p.A316= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV54008346; called by muse, mutect2, varscan2
- GNAT2 | c.525C>G p.L175= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs749110943, COSV63554670; called by muse, mutect2, varscan2
- GPR83 | c.369C>G p.L123= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54717722; called by muse, mutect2, varscan2
- GRIN2A | c.3975C>T p.Y1325= | Silent (SNP) | VAF 57/134 reads (43%) | catalogued as rs545080350, COSV58022561; called by muse, mutect2, varscan2
- H2BC4 | c.222C>T p.I74= | Silent (SNP) | VAF 51/206 reads (25%) | catalogued as rs748922417, COSV58415038, COSV58416773; called by muse, mutect2, varscan2
- KCNT1 | c.3472C>T p.L1158= (on ENST00000488444; = p.L1139= on NM_001272003.2) | Silent (SNP) | VAF 47/149 reads (32%) | catalogued as COSV99706735; called by muse, mutect2, varscan2
- KIAA2026 | c.4485G>A p.A1495= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs754632331, COSV67353516; called by muse, mutect2, varscan2
- KRT72 | c.549G>T p.L183= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as COSV53373356; called by muse, mutect2
- MIEF1 | c.570C>G p.L190= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as rs750355881, COSV57477713; called by muse, mutect2, varscan2
- MYH11 | c.3243C>G p.L1081= | Silent (SNP) | VAF 62/276 reads (22%) | catalogued as COSV55544667; called by muse, mutect2, varscan2
- MYT1L | c.3348C>T p.L1116= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs1189140761, COSV67701521; called by muse, mutect2, varscan2
- NID1 | c.549A>G p.L183= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV51615643; called by muse, mutect2, varscan2
- PALLD | c.2631C>T p.I877= (on ENST00000505667 / NM_001166108.2; = p.I860= on NM_016081.4) | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV54974263; called by muse, mutect2, varscan2
- PCDHGA3 | c.1644G>A p.L548= | Silent (SNP) | VAF 124/285 reads (44%) | catalogued as COSV53906936; called by muse, mutect2, varscan2
- PER2 | c.426C>T p.L142= | Silent (SNP) | VAF 11/248 reads (4%) | catalogued as COSV54521707; called by muse, mutect2
- PICK1 | c.777G>A p.E259= | Silent (SNP) | VAF 40/127 reads (31%) | catalogued as COSV63659626; called by muse, mutect2, varscan2
- PILRA | c.345G>T p.L115= | Silent (SNP) | VAF 12/316 reads (4%) | catalogued as COSV52199405, COSV99546801; called by muse, mutect2
- PITRM1 | c.864C>T p.F288= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56527127; called by muse, mutect2, varscan2
- PMEPA1 | c.636G>A p.S212= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as COSV55691927; called by muse, mutect2, varscan2
- PPP2R1B | c.1371T>C p.S457= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV59534815; called by muse, mutect2, varscan2
- RANBP2 | c.6858G>A p.Q2286= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs750961259, COSV51697195, COSV51699452; called by muse, mutect2, varscan2
- RBBP7 | c.232C>T p.L78= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV66300379; called by muse, mutect2, varscan2
- RELN | c.10107C>T p.I3369= | Silent (SNP) | VAF 67/200 reads (34%) | catalogued as COSV58987921; called by muse, mutect2, varscan2
- RHD | c.459G>A p.L153= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV59645398; called by muse, mutect2, varscan2
- RTKN | c.1426C>T p.L476= (on ENST00000272430 / NM_001015055.2; = p.L463= on NM_033046.2) | Silent (SNP) | VAF 20/107 reads (19%) | catalogued as COSV51961705; called by muse, mutect2, varscan2
- S1PR4 | c.357C>T p.F119= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV55739608; called by muse, mutect2, varscan2
- S1PR5 | c.945C>T p.H315= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV61013357; called by muse, mutect2, varscan2
- SFI1 | c.3240G>A p.P1080= (on ENST00000400288 / NM_001007467.3; = p.P1049= on NM_014775.4) | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs753512119, COSV56716222; called by muse, varscan2
- SLC27A1 | c.153G>C p.A51= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as COSV53095587; called by muse, varscan2
- SNX4 | c.423C>G p.L141= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV52536289; called by muse, mutect2, varscan2
- TUFM | c.441C>T p.L147= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as rs759117049, COSV57948364; called by muse, mutect2
- VAV2 | c.765G>A p.L255= (on ENST00000371850 / NM_001134398.2; = p.L250= on NM_003371.4) | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64080342; called by muse, mutect2, varscan2
- ZNF831 | c.3663C>T p.P1221= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV100926144, COSV64037884; called by muse, mutect2, varscan2
- CDK14 | c.124-16972C>T | Intron (SNP) | VAF 5/41 reads (12%) | catalogued as rs751679131, COSV56057844; called by muse, mutect2, varscan2
- DBT | c.*2G>C | 3'UTR (SNP) | VAF 16/62 reads (26%) | catalogued as COSV100923766; called by muse, mutect2, varscan2
- LRRC17 | c.-1G>C | 5'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99978683; called by muse, mutect2
- MON2 | chr12:62603112 G>C | 3'Flank (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- PAK6 | c.-117-680C>G | Intron (SNP) | VAF 6/36 reads (17%) | catalogued as rs373664252, COSV99544407; called by muse, mutect2, varscan2
- RNU6-104P | chr8:43302025 C>G | 5'Flank (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
